Somatic mutation profile of tumor specimen TCGA-FJ-A3ZE-01A (aliquot TCGA-FJ-A3ZE-01A-11D-A23M-08) from TCGA case TCGA-FJ-A3ZE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.3 years (23,866 days).
Specimen TCGA-FJ-A3ZE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ab9678d-79c6-48ae-8b56-bfc663ac7066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FJ-A3ZE-10A (Blood Derived Normal), aliquot TCGA-FJ-A3ZE-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6e29123-1e6a-4d8f-a487-b1d294571978

The open-access MAF lists 478 somatic variants for this specimen: 354 protein-altering or splice-affecting, 111 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 316, Silent 111, Nonsense Mutation 12, Frame Shift Del 12, Splice Site 10, RNA 4, Frame Shift Ins 3, 3'UTR 3, 5'UTR 2, 5'Flank 2, Intron 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PAH | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs62508695, CM992650, COSV61019022; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 60/69 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.1322A>G p.Q441R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV55958281; called by muse, varscan2
- ABCC11 | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.345); catalogued as COSV62324855; called by muse, mutect2, varscan2
- ABRAXAS2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as rs866654451, COSV53716351; called by muse, mutect2, varscan2
- ACBD7 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs756627997, COSV62252166; called by muse, mutect2, varscan2
- ACOX3 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.166); catalogued as rs780165236, COSV62713115; called by muse, mutect2, varscan2
- ACTL7A | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV61776289; called by muse, mutect2, varscan2
- ADAM22 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV55976154; called by muse, mutect2
- ADAM32 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.191); catalogued as rs142346085; called by muse, mutect2, varscan2
- ADAMTS12 | c.3385T>A p.L1129M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV61272099; called by muse, mutect2, varscan2
- ADAMTS5 | c.2516C>A p.P839H | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as COSV53182587; called by muse, mutect2, varscan2
- ADGRA2 | c.2892G>T p.R964S | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.056); catalogued as COSV55104860; called by muse, mutect2, varscan2
- AHR | c.1991G>T p.C664F | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as COSV54125206; called by muse, mutect2, varscan2
- ALDH1L2 | c.776T>A p.I259K | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV51558293; called by muse, mutect2, varscan2
- AMBN | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs141401324; called by muse, mutect2, varscan2
- AMER3 | c.1696C>G p.Q566E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs776718013, COSV58468478, COSV58468700; called by muse, mutect2, varscan2
- ANGPT4 | c.473A>T p.N158I | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV67922285, COSV67922401; called by muse, mutect2, varscan2
- ANK2 | c.6640C>A p.P2214T | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52177872, COSV52183506; called by muse, mutect2, varscan2
- APOA4 | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 124/258 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV63360663, COSV63360992; called by muse, mutect2, varscan2
- ARHGAP31 | c.1664C>A p.A555E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV51796811; called by muse, mutect2
- ARVCF | c.1759C>A p.P587T | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54268702; called by muse, mutect2, varscan2
- ASTN1 | c.2765C>T p.T922I | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV62501859; called by muse, mutect2, varscan2
- ATRNL1 | c.1445A>T p.Y482F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV61811351; called by muse, mutect2, varscan2
- ATXN3 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 143/309 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as COSV61496901; called by muse, mutect2, varscan2
- B4GALT1 | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65708651; called by muse, mutect2, varscan2
- BACH2 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.107); catalogued as COSV57590197, COSV57602173; called by muse, mutect2, varscan2
- BIRC6 | c.8203A>C p.N2735H | Missense Mutation (SNP) | VAF 73/81 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV70203571; called by muse, mutect2, varscan2
- BRF2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 147/181 reads (81%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as COSV55104870; called by muse, mutect2, varscan2
- BUD23 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56095861; called by muse, mutect2, varscan2
- C11orf58 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV57178980; called by muse, mutect2, varscan2
- C16orf78 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54557625; called by muse, mutect2, varscan2
- C3 | c.2888C>A p.P963Q | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as rs1028081640, COSV55577976; called by muse, mutect2, varscan2
- C6orf62 | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65290961; called by muse, mutect2, varscan2
- CACNA1S | c.4540G>A p.G1514R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62942109; called by muse, mutect2, varscan2
- CAMSAP1 | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56725928; called by muse, mutect2, varscan2
- CAPRIN2 | c.2728G>T p.G910C | Missense Mutation (SNP) | VAF 164/329 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); catalogued as COSV51834291; called by muse, mutect2, varscan2
- CBX1 | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 102/199 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV56682437; called by muse, mutect2, varscan2
- CCDC18 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.218); catalogued as COSV58146030; called by muse, mutect2, varscan2
- CCT3 | c.354C>G p.H118Q | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55290539; called by muse, mutect2, varscan2
- CDH5 | c.2178C>A p.D726E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58519031; called by muse, mutect2, varscan2
- CELF4 | c.938C>A p.T313N | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs1406619839, COSV100611922, COSV58461150; called by muse, mutect2, varscan2
- CEP104 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV65518700; called by muse, mutect2, varscan2
- CEP290 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV58354227; called by muse, mutect2, varscan2
- CERKL | c.1450T>A p.F484I (on ENST00000339098 / NM_001030311.2; = p.F458I on NM_201548.5) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV59211308; called by muse, mutect2, varscan2
- CHD6 | c.7716G>C p.K2572N | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV64693073; called by muse, mutect2, varscan2
- CLEC14A | c.1245G>C p.M415I | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60563636; called by muse, mutect2, varscan2
- CLN3 | c.830G>T p.G277V (on ENST00000360019 / NM_001286104.2; = p.G301V on NM_000086.2) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV61107026; called by muse, mutect2, varscan2
- CNNM3 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV100562795; called by muse, mutect2, varscan2
- CNTN4 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761504879, COSV61877512; called by muse, mutect2, varscan2
- COL14A1 | c.3073+1G>A p.X1025_splice | Splice Site (SNP) | VAF 80/174 reads (46%) | catalogued as COSV52862811; called by muse, mutect2, varscan2
- COL19A1 | c.2740G>T p.G914C | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59581053; called by muse, mutect2, varscan2
- COL1A1 | c.2051A>G p.E684G | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56808142; called by muse, mutect2, varscan2
- COL6A3 | c.5413C>G p.L1805V | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55100577; called by muse, mutect2, varscan2
- CPNE3 | c.1329T>G p.N443K | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.099); catalogued as COSV52208809; called by muse, mutect2, varscan2
- CPNE8 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100504661, COSV58848302; called by muse, mutect2, varscan2
- CTNND2 | c.1763T>G p.I588R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58910591; called by muse, mutect2, varscan2
- CTTNBP2 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV50437870; called by muse, mutect2, varscan2
- CUBN | c.9706T>C p.F3236L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV64722757; called by muse, mutect2, varscan2
- CYP7A1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV100052451, COSV56964752; called by muse, mutect2, varscan2
- DCAF8 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 51/139 reads (37%) | catalogued as COSV100470545; called by muse, mutect2, varscan2
- DCLRE1A | c.2849G>C p.G950A | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV63749393; called by muse, mutect2, varscan2
- DIAPH3 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 112/258 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57376398; called by muse, mutect2, varscan2
- DLG5 | c.4282A>T p.N1428Y | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV64949050; called by muse, mutect2, varscan2
- DLGAP2 | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 66/74 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1349496664, COSV70099952, COSV70102010; called by muse, mutect2, varscan2
- DMXL1 | c.3905C>A p.P1302H | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.643); catalogued as COSV60717936; called by muse, mutect2, varscan2
- DPP4 | c.1940T>C p.F647S | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62108576; called by muse, mutect2, varscan2
- DSC1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57147631; called by muse, mutect2, varscan2
- DSCAML1 | c.5805G>T p.K1935N (on ENST00000321322; = p.K1875N on NM_020693.4) | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58398237; called by muse, mutect2, varscan2
- DUSP13 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.242); catalogued as rs777260250, COSV57815582; called by muse, mutect2, varscan2
- DYNC1H1 | c.9982C>A p.L3328M | Missense Mutation (SNP) | VAF 183/300 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV64140106; called by muse, mutect2, varscan2
- EFHB | c.2050C>G p.L684V | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV55551356; called by muse, mutect2, varscan2
- EMSY | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV58260340; called by muse, mutect2, varscan2
- ENTPD8 | c.881A>C p.H294P | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV58163000; called by muse, mutect2, varscan2
- EPS8L2 | c.1063del p.V355Sfs*94 | Frame Shift Del (DEL) | VAF 43/63 reads (68%) | catalogued as COSV59349365; called by mutect2, pindel, varscan2
- EYA1 | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV58169275, COSV58174564; called by muse, mutect2, varscan2
- FAM111B | c.1924G>C p.D642H | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs750262307, COSV59112933; called by muse, mutect2, varscan2
- FAM53A | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57402633; called by muse, mutect2, varscan2
- FAM98C | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV53039409; called by muse, mutect2, varscan2
- FAT2 | c.5572G>C p.V1858L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55825843; called by muse, mutect2, varscan2
- FAT2 | c.3106G>T p.V1036L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as COSV55816319, COSV55825854; called by muse, mutect2, varscan2
- FAT4 | c.6263C>T p.T2088I | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as rs751898927, COSV58699817; called by muse, mutect2, varscan2
- FBF1 | c.2277G>T p.E759D (on ENST00000586717; = p.E773D on NM_001319193.1) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV59866246; called by muse, mutect2, varscan2
- FBN3 | c.4085A>G p.D1362G | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1211197311, COSV54467808; called by muse, mutect2, varscan2
- FBXL7 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs761869950, COSV61645513; called by muse, mutect2, varscan2
- FGD6 | c.3751G>A p.V1251I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as COSV59693384, COSV59695529; called by muse, mutect2, varscan2
- FLRT3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568696965, COSV54022946; called by muse, mutect2, varscan2
- FMN2 | c.3922G>C p.D1308H | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV60443756, COSV60453807; called by muse, mutect2, varscan2
- FPGT | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63844223; called by muse, mutect2, varscan2
- FUT5 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53137815; called by muse, mutect2, varscan2
- GABBR2 | c.1531C>T p.L511F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV52313521; called by muse, mutect2, varscan2
- GABRR1 | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.065); catalogued as COSV65620105; called by muse, mutect2, varscan2
- GARRE1 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV55097690; called by muse, mutect2, varscan2
- GEN1 | c.1661A>C p.Q554P | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV58057854; called by muse, mutect2, varscan2
- GMPS | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 173/343 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV55810936; called by muse, mutect2, varscan2
- GNG4 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64000008; called by muse, mutect2, varscan2
- GRIK2 | c.1867G>A p.G623S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV59756182; called by muse, mutect2, varscan2
- GRM6 | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 90/121 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51447282; called by muse, mutect2, varscan2
- GTF3C1 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 120/239 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs1309495650, COSV62243379; called by muse, mutect2, varscan2
- HCK | c.683-1G>C p.X228_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV52945597; called by muse, mutect2, varscan2
- HECW1 | c.2678C>G p.A893G | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV101224254, COSV67836427; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.429A>G p.I143M (on ENST00000354667 / NM_031243.3; = p.I131M on NM_002137.4) | Missense Mutation (SNP) | VAF 109/207 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61160512; called by muse, mutect2, varscan2
- HSD17B1 | c.26C>G p.T9S | Missense Mutation (SNP) | VAF 64/69 reads (93%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV56798365; called by muse, mutect2, varscan2
- HTR1F | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100137898, COSV60390760; called by muse, mutect2, varscan2
- HUNK | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV54231882; called by muse, mutect2, varscan2
- HUS1B | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs778160260, COSV57869506; called by muse, mutect2, varscan2
- IGHV3-43 | c.226A>T p.S76C | Missense Mutation (SNP) | VAF 350/517 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs1266633840; called by muse, mutect2, varscan2
- IL23A | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV57336214; called by muse, mutect2, varscan2
- IMP4 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.261); catalogued as rs758833241, COSV52092378; called by muse, mutect2, varscan2
- IMPG1 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV64060110; called by muse, mutect2, varscan2
- INF2 | c.1775C>A p.A592D | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV53035011; called by muse, mutect2, varscan2
- INHBB | c.938G>C p.R313P | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54677570, COSV54678018, COSV54678798; called by muse, mutect2, varscan2
- INSL4 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV53329072, COSV53329665; called by muse, mutect2, varscan2
- ITGA1 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50891041; called by muse, mutect2, varscan2
- ITGA5 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs897973104, COSV53219701; called by muse, mutect2, varscan2
- KALRN | c.1358C>G p.A453G | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV53774623, COSV99563472; called by muse, mutect2, varscan2
- KCNJ13 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52085685; called by muse, mutect2, varscan2
- KCNJ14 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs770005092, COSV53520013; called by muse, mutect2, varscan2
- KCNS2 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as COSV54639950; called by muse, mutect2, varscan2
- KIAA1217 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64610083; called by muse, mutect2
- KLK15 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs970257706, COSV56827801; called by muse, mutect2, varscan2
- KRT2 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59011881; called by muse, mutect2, varscan2
- KRT83 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV53341616; called by muse, mutect2, varscan2
- LCA5L | c.704T>C p.L235S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs960875553, COSV55746597; called by muse, mutect2, varscan2
- LMOD1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs1451879890, COSV66172069; called by muse, mutect2, varscan2
- LONP1 | c.2633C>G p.A878G | Missense Mutation (SNP) | VAF 63/74 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56799253; called by muse, mutect2, varscan2
- LPGAT1 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 116/269 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV65352161; called by muse, mutect2, varscan2
- LRCH1 | c.482G>C p.C161S | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1213927363, COSV60850939; called by muse, mutect2, varscan2
- LRFN1 | c.1338G>T p.R446S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV50486502; called by muse, mutect2, varscan2
- LSAMP | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61304085; called by muse, mutect2, varscan2
- MAGEB18 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV57463498, COSV57464684; called by muse, mutect2, varscan2
- MAMDC4 | c.2058C>A p.D686E (on ENST00000445819; = p.D607E on NM_206920.3) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58073019; called by muse, mutect2, varscan2
- MAML2 | c.3209A>G p.N1070S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); catalogued as COSV73264312; called by muse, mutect2, varscan2
- MAP10 | c.1670G>T p.S557I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV69364444; called by muse, mutect2, varscan2
- MAP3K13 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53993666; called by muse, mutect2, varscan2
- MAPK12 | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535912053, COSV53134513, COSV99299378; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1861G>T p.D621Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50504848; called by muse, mutect2, varscan2
- MARVELD3 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1050749584, COSV51705497; called by muse, mutect2, varscan2
- MATN4 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV59215135; called by muse, mutect2, varscan2
- MAVS | c.1047G>T p.L349F | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63927301; called by muse, mutect2, varscan2
- MEGF10 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs765998227, COSV57245961, COSV57253910; called by muse, mutect2, varscan2
- MFN2 | c.481A>G p.N161D | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV52424467; called by muse, mutect2, varscan2
- MGAM | c.2528C>A p.A843D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV72075225; called by muse, mutect2, varscan2
- MIER1 | c.751A>G p.K251E (on ENST00000355356 / NM_001077701.3; = p.K268E on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62531336; called by muse, mutect2, varscan2
- MIOS | c.2309C>A p.S770Y | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV60769929; called by muse, mutect2, varscan2
- MIPOL1 | c.624-1G>C p.X208_splice | Splice Site (SNP) | VAF 41/105 reads (39%) | catalogued as COSV59389489; called by muse, mutect2, varscan2
- MKI67 | c.3170A>C p.E1057A | Missense Mutation (SNP) | VAF 181/307 reads (59%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.608); catalogued as COSV64075762; called by muse, mutect2, varscan2
- MMP10 | c.897C>A p.S299R | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54247053; called by muse, mutect2, varscan2
- MMP2 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54603772, COSV54605234; called by muse, mutect2, varscan2
- MMP20 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as COSV52777170; called by muse, mutect2
- MMRN1 | c.1913A>G p.Q638R | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV53340729; called by muse, mutect2, varscan2
- MORC3 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as COSV68688862; called by muse, mutect2, varscan2
- MSANTD4 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs769889206, COSV57286539; called by muse, mutect2, varscan2
- MSH2 | c.1816G>T p.V606F | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51882546; called by muse, mutect2, varscan2
- MTA2 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV53471252; called by muse, mutect2, varscan2
- MTMR3 | c.2371G>T p.V791F | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.049); catalogued as rs748770150, COSV60307255; called by muse, mutect2, varscan2
- MUC16 | c.37996C>T p.P12666S | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs762490369, COSV67481340, COSV67483000; called by muse, mutect2, varscan2
- MUC16 | c.30326C>A p.T10109N | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.783); catalogued as COSV67481342; called by muse, mutect2, varscan2
- MUC16 | c.29444C>A p.A9815D | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV67481346; called by muse, mutect2, varscan2
- MUC16 | c.5690C>A p.T1897N | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV67481350; called by muse, mutect2, varscan2
- MUC16 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 108/137 reads (79%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV67481354, COSV67496641; called by muse, mutect2, varscan2
- MUC6 | c.4557C>G p.N1519K | Missense Mutation (SNP) | VAF 138/148 reads (93%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs762266429, COSV70146543; called by muse, mutect2, varscan2
- MYH4 | c.4097C>G p.S1366C | Missense Mutation (SNP) | VAF 113/122 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55123227; called by muse, mutect2, varscan2
- MYLK3 | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV67365788; called by muse, mutect2
- MYO1B | c.1982+1G>C p.X661_splice | Splice Site (SNP) | VAF 16/37 reads (43%) | catalogued as rs757926686, COSV58435428; called by muse, mutect2, varscan2
- MYO1B | c.2818G>T p.E940* (on ENST00000304164; = p.E882* on NM_012223.5) | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100270114; called by muse, mutect2, varscan2
- NALCN | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51951855; called by muse, mutect2, varscan2
- NANOS3 | c.278G>A p.C93Y (on ENST00000397555; = p.C112Y on NM_001098622.2) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59249506; called by muse, mutect2, varscan2
- NAT9 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52854286; called by muse, mutect2, varscan2
- NCKAP1L | c.1145G>T p.W382L | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53210192; called by muse, mutect2, varscan2
- NDNF | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV101113198; called by muse, mutect2, varscan2
- NEK10 | c.1853C>A p.S618Y | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs372441033, COSV58286421; called by muse, mutect2, varscan2
- NEK5 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs777989531; called by muse, mutect2
- NLRC3 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1480875045, COSV57093879; called by muse, mutect2, varscan2
- NODAL | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54660951, COSV54662177; called by muse, mutect2, varscan2
- NPFFR2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58152416; called by muse, mutect2, varscan2
- NPNT | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1372061113, COSV59755904; called by muse, mutect2, varscan2
- NR2F2 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.395); catalogued as COSV67683479, COSV67683926; called by muse, mutect2, varscan2
- NRP2 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV55923849, COSV55932634; called by muse, mutect2, varscan2
- OLFM2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV53432525; called by muse, mutect2, varscan2
- OR10A6 | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59165638; called by muse, mutect2, varscan2
- OR2C3 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs778788116, COSV63574587, COSV63575312; called by muse, mutect2, varscan2
- OR4K17 | c.463C>G p.H155D | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59648742, COSV59649214; called by muse, mutect2, varscan2
- OR52N4 | c.14A>C p.N5T | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57892060; called by muse, mutect2, varscan2
- OR56A1 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57363428; called by muse, mutect2, varscan2
- OR5T1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs748261639, COSV57303984; called by muse, mutect2, varscan2
- OR8K5 | c.581A>C p.E194A | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs1335288552, COSV57890244; called by muse, mutect2, varscan2
- OTUD7A | c.1967T>C p.F656S (on ENST00000307050 / NM_001382637.1; = p.F649S on NM_130901.3) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61041569; called by muse, mutect2, varscan2
- P4HB | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 211/359 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58942422; called by muse, mutect2, varscan2
- PAAF1 | c.768G>C p.L256F | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV60156613, COSV60157175; called by muse, mutect2, varscan2
- PALD1 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54976888; called by muse, mutect2, varscan2
- PARM1 | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1369384617, COSV56657095; called by muse, mutect2, varscan2
- PATJ | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57168073; called by muse, mutect2, varscan2
- PCDHA1 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 101/148 reads (68%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); catalogued as COSV65375958; called by muse, mutect2, varscan2
- PCDHGA6 | c.2310C>A p.F770L | Missense Mutation (SNP) | VAF 91/126 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV53952971, COSV53998154; called by muse, mutect2, varscan2
- PCYT1A | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53059109; called by muse, mutect2, varscan2
- PEX3 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV62569234; called by muse, mutect2, varscan2
- PIDD1 | c.1965G>T p.E655D | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV57192355; called by muse, mutect2, varscan2
- PIK3R2 | c.1028A>G p.K343R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV55849399; called by muse, mutect2, varscan2
- PKD1L2 | c.1446del p.T483Pfs*16 | Frame Shift Del (DEL) | VAF 56/129 reads (43%) | catalogued as COSV61418040; called by mutect2, pindel, varscan2
- PKHD1L1 | c.9029G>A p.C3010Y | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV65748826; called by muse, mutect2, varscan2
- PLXNB3 | c.2420G>A p.C807Y | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62800327; called by muse, mutect2, varscan2
- PLXND1 | c.4371G>T p.E1457D | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60715754; called by muse, mutect2, varscan2
- PMEL | c.1559T>G p.L520R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59387676; called by muse, mutect2, varscan2
- PNPLA3 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV53379800; called by muse, mutect2, varscan2
- PPFIA2 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100333478, COSV61041031; called by muse, mutect2
- PPFIA3 | c.2799del p.T934Pfs*19 | Frame Shift Del (DEL) | VAF 45/110 reads (41%) | catalogued as COSV61953625; called by mutect2, pindel, varscan2
- PRPH2 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV57838103; called by muse, mutect2, varscan2
- PSD4 | c.1009G>C p.A337P | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV55528685; called by muse, mutect2, varscan2
- PSMB1 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV51531498; called by muse, mutect2
- PTGES2 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs769737166, COSV52969051; called by muse, mutect2, varscan2
- PTK2B | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57762446; called by muse, mutect2, varscan2
- PTPN3 | c.1691del p.G564Afs*13 | Frame Shift Del (DEL) | VAF 110/298 reads (37%) | catalogued as COSV52707477; called by mutect2, pindel, varscan2
- PTPRC | c.2698-1G>T p.X900_splice | Splice Site (SNP) | VAF 37/65 reads (57%) | catalogued as COSV61409459; called by muse, mutect2, varscan2
- PTPRN2 | c.1645G>T p.V549F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs536072975, COSV67053300; called by muse, mutect2, varscan2
- PTPRU | c.3031G>C p.D1011H | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60530207, COSV60533479; called by muse, mutect2, varscan2
- PUS3 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as COSV57104029; called by muse, mutect2, varscan2
- PXDN | c.3071C>A p.A1024E | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53241842; called by mutect2, varscan2
- QSOX1 | c.1736A>G p.D579G | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62581188; called by muse, mutect2, varscan2
- RAB36 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54075865; called by muse, mutect2, varscan2
- RABEP2 | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0.054); catalogued as rs745787339, COSV62870383; called by muse, mutect2, varscan2
- RANBP9 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.734); catalogued as COSV50584066; called by muse, mutect2, varscan2
- RBAK | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs1414956442; called by muse, mutect2, varscan2
- RCOR3 | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV65366444; called by muse, mutect2, varscan2
- RCSD1 | c.39C>A p.D13E | Missense Mutation (SNP) | VAF 131/494 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs976913898, COSV63260240; called by muse, mutect2, varscan2
- RGS19 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 71/106 reads (67%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV58658807; called by muse, mutect2, varscan2
- RINT1 | c.997-2A>G p.X333_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | catalogued as COSV57559777; called by muse, varscan2
- RNASE9 | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as rs950228882; called by muse, mutect2, varscan2
- RNF112 | c.1672C>T p.L558F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101465414; called by muse, mutect2, varscan2
- RNF183 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV52908080; called by muse, mutect2, varscan2
- RNF215 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53176715; called by muse, mutect2, varscan2
- ROBO3 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV67302010; called by muse, mutect2, varscan2
- RPS6KC1 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65301613; called by mutect2, varscan2
- RRBP1 | c.1844G>T p.S615I (on ENST00000377813 / NM_001365613.2; = p.S185I on NM_004587.3) | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.937); catalogued as rs770088879, COSV55705157; called by muse, mutect2, varscan2
- RYR2 | c.3629C>A p.A1210D | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV63702324; called by muse, mutect2, varscan2
- SAMD14 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 102/189 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs1309004719, COSV53310755; called by muse, mutect2, varscan2
- SCFD1 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV61725884; called by muse, mutect2, varscan2
- SCN1A | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57680443; called by muse, mutect2, varscan2
- SCN1A | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57680480; called by muse, mutect2, varscan2
- SDK1 | c.3775G>T p.G1259W | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101269430, COSV67381518; called by muse, mutect2, varscan2
- SEPTIN1 | c.643G>T p.V215F (on ENST00000321367; = p.V168F on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58443094; called by muse, mutect2, varscan2
- SGIP1 | c.1224A>T p.R408S | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV52775251; called by muse, mutect2, varscan2
- SH3PXD2A | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 120/195 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63512226; called by muse, mutect2, varscan2
- SIDT1 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV53504492; called by muse, mutect2, varscan2
- SLAMF8 | c.673+1G>A p.X225_splice | Splice Site (SNP) | VAF 111/174 reads (64%) | catalogued as rs754643302, COSV56989408; called by muse, mutect2, varscan2
- SLC12A1 | c.2372C>A p.T791K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66797720; called by muse, mutect2, varscan2
- SLC12A7 | c.2506C>A p.Q836K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV53760243; called by muse, mutect2, varscan2
- SLC13A4 | c.1365G>C p.W455C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62462230; called by muse, mutect2, varscan2
- SLC34A1 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as COSV60998003, COSV60998514; called by muse, mutect2, varscan2
- SLC6A3 | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV54367369; called by muse, mutect2, varscan2
- SLC9A4 | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as COSV54837129; called by muse, mutect2, varscan2
- SLIT1 | c.1466-2A>G p.X489_splice | Splice Site (SNP) | VAF 45/173 reads (26%) | catalogued as COSV56595096; called by muse, mutect2, varscan2
- SLITRK3 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.9); catalogued as COSV53851398; called by muse, mutect2, varscan2
- SMARCA2 | c.3505G>T p.V1169F | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61810489; called by muse, mutect2, varscan2
- SMARCA4 | c.3547G>C p.D1183H | Missense Mutation (SNP) | VAF 117/169 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60789520, COSV60791425; called by muse, mutect2, varscan2
- SMTN | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs767387915, COSV60781141; called by muse, mutect2, varscan2
- SNX25 | c.457A>G p.N153D | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53016949; called by muse, varscan2
- SNX27 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64327096; called by muse, mutect2, varscan2
- SORBS1 | c.3265C>A p.Q1089K | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53362237; called by muse, mutect2, varscan2
- SPDYE1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.259); catalogued as COSV51671538; called by muse, mutect2, varscan2
- SPEF2 | c.2264A>C p.K755T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV61551633; called by muse, mutect2, varscan2
- SPTA1 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63757170; called by muse, mutect2, varscan2
- SPTLC3 | c.1407del p.V471* | Frame Shift Del (DEL) | VAF 26/115 reads (23%) | catalogued as COSV65463708, COSV65467289; called by mutect2, pindel, varscan2
- SREBF1 | c.2383G>C p.V795L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV55393751, COSV55396412; called by muse, mutect2, varscan2
- SRSF12 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV71683745; called by muse, mutect2, varscan2
- ST8SIA3 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 25/46 reads (54%) | PolyPhen benign (0.015); catalogued as COSV60654129, COSV60654864; called by muse, mutect2, varscan2
- STX18 | c.419A>T p.D140V | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60374833; called by muse, mutect2, varscan2
- STYXL2 | c.2434T>G p.C812G | Missense Mutation (SNP) | VAF 95/149 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54808178; called by muse, mutect2, varscan2
- SVIL | c.5537T>A p.V1846D (on ENST00000355867 / NM_021738.3; = p.V1420D on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63446208; called by muse, mutect2, varscan2
- TANC2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 130/210 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV101267641, COSV67338596; called by muse, varscan2
- TAS2R9 | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as COSV53689459; called by muse, mutect2, varscan2
- TGM1 | c.2041G>T p.A681S | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52864516; called by muse, mutect2, varscan2
- TGS1 | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52702090; called by muse, mutect2, varscan2
- THSD7B | c.4333A>T p.N1445Y (on ENST00000272643; = p.N1443Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55717713; called by muse, mutect2, varscan2
- TIMM29 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 107/150 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV53404606; called by muse, mutect2, varscan2
- TMBIM6 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1314408803, COSV57280499; called by muse, mutect2, varscan2
- TMC2 | c.1873-1G>T p.X625_splice | Splice Site (SNP) | VAF 31/76 reads (41%) | catalogued as COSV62656372; called by muse, mutect2, varscan2
- TMEM131 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.326); catalogued as COSV51782496; called by muse, mutect2, varscan2
- TMEM143 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV53156301, COSV53158109; called by muse, mutect2, varscan2
- TMEM143 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV53158129; called by muse, mutect2, varscan2
- TMPRSS11D | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385029; called by muse, varscan2
- TMPRSS2 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV59825728; called by muse, mutect2, varscan2
- TMX4 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV55681866; called by muse, mutect2, varscan2
- TNFRSF1B | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 64/70 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66164240, COSV66164820; called by muse, mutect2, varscan2
- TOP3A | c.2618G>T p.C873F | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58179812; called by muse, mutect2, varscan2
- TRIM59 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV59088079; called by muse, mutect2, varscan2
- TUBA3D | c.80A>G p.E27G | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV58312764; called by muse, mutect2, varscan2
- TULP2 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760643540, COSV55479325; called by muse, mutect2, varscan2
- TUT7 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV52897578; called by muse, mutect2, varscan2
- UBE2S | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV52740697; called by muse, mutect2, varscan2
- UBR4 | c.15323A>C p.K5108T | Missense Mutation (SNP) | VAF 49/51 reads (96%) | SIFT tolerated (0.14); PolyPhen benign (0.31); catalogued as COSV64395407; called by muse, mutect2, varscan2
- UNC13C | c.5405A>G p.Q1802R | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV52904293; called by muse, mutect2, varscan2
- UNC5C | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV71661344; called by muse, mutect2, varscan2
- USP24 | c.6884A>C p.Q2295P | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV53774346; called by muse, mutect2, varscan2
- USP7 | c.611+1G>A p.X204_splice | Splice Site (SNP) | VAF 39/95 reads (41%) | catalogued as COSV61216393; called by muse, mutect2, varscan2
- VAV1 | c.1117G>T p.V373F | Missense Mutation (SNP) | VAF 37/682 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58388434, COSV58391100; called by muse, mutect2
- VGLL4 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56075553, COSV56080127; called by muse, mutect2, varscan2
- VPS13C | c.11223G>T p.Q3741H (on ENST00000644861 / NM_020821.3; = p.Q3698H on NM_017684.5) | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV51350872; called by muse, mutect2, varscan2
- VRTN | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV56442678; called by muse, mutect2, varscan2
- WDFY3 | c.10415G>C p.R3472T | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55709576, COSV55716211; called by muse, mutect2, varscan2
- WDR1 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53332523, COSV99059208; called by muse, mutect2, varscan2
- WDR17 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54579540; called by muse, mutect2, varscan2
- XPO4 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55010963; called by muse, mutect2, varscan2
- ZDBF2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV65628536; called by muse, mutect2, varscan2
- ZFP36L1 | c.784T>C p.F262L | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.977); catalogued as COSV60546619; called by muse, varscan2
- ZMYND8 | c.347G>T p.R116I (on ENST00000311275 / NM_001363741.2; = p.R136I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53693424; called by muse, mutect2, varscan2
- ZNF141 | c.1393C>A p.H465N | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53660468, COSV53662346; called by muse, mutect2, varscan2
- ZNF485 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs138982373; called by muse, mutect2, varscan2
- ZNF646 | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs781660371, COSV56217361; called by muse, mutect2, varscan2
- ZNF668 | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56217345; called by muse, mutect2, varscan2
- ZNF682 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV62068036; called by muse, mutect2, varscan2
- ZNF773 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.193); catalogued as COSV56589641; called by muse, mutect2, varscan2
- ZNF827 | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV65230070; called by muse, mutect2, varscan2
- ZNF839 | c.154G>C p.D52H (on ENST00000558850 / NM_001267827.1; = p.D168H on NM_018335.5) | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1231007186, COSV51758666; called by muse, mutect2, varscan2
- ZNF846 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV67412382; called by muse, mutect2, varscan2
- ACTL7B | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- ADCY1 | c.2203del p.L735Wfs*7 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- AKAP8L | c.1696G>C p.A566P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP15 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.576T>G p.N192K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B4 | c.2023G>T p.G675* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- CELSR3 | c.7144A>G p.S2382G | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP250 | c.3439G>A p.A1147T | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CILP2 | c.138del p.S47Hfs*69 | Frame Shift Del (DEL) | VAF 54/168 reads (32%) | called by mutect2, pindel
- DOCK9 | c.2874C>A p.Y958* (on ENST00000376460 / NM_001366676.2; = p.Y959* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- DSC2 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DZIP1 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- ECPAS | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EIF3B | c.1026G>A p.W342* | Nonsense Mutation (SNP) | VAF 105/206 reads (51%) | called by muse, mutect2, varscan2
- EIF3J | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- FRG2C | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- GATA5 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- H2BC3 | c.322del p.A108Lfs*? | Frame Shift Del (DEL) | VAF 43/110 reads (39%) | called by mutect2, pindel, varscan2
- IGHG3 | c.993C>A p.D331E | Missense Mutation (SNP) | VAF 133/738 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KDM6A | c.1042dup p.D348Gfs*16 | Frame Shift Ins (INS) | VAF 33/51 reads (65%) | called by mutect2, pindel, varscan2
- KL | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- MAFB | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- NBPF11 | c.1666G>T p.V556F | Missense Mutation (SNP) | VAF 127/323 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- QTRT1 | c.766dup p.R256Pfs*11 | Frame Shift Ins (INS) | VAF 32/309 reads (10%) | called by mutect2, pindel, varscan2
- RGL2 | c.1261dup p.S421Ffs*29 | Frame Shift Ins (INS) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- SCNN1B | c.1386G>A p.W462* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- SH3TC2 | c.912del p.L305Ffs*22 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | called by mutect2, varscan2
- SLCO1B3 | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- STAG2 | c.989_990del p.K330Ifs*8 | Frame Shift Del (DEL) | VAF 120/175 reads (69%) | called by mutect2, pindel, varscan2
- TRAJ29 | c.47T>A p.L16H | Missense Mutation (SNP) | VAF 56/140 reads (40%) | called by muse, mutect2, varscan2
- TRIB3 | c.918del p.T307Qfs*16 | Frame Shift Del (DEL) | VAF 39/237 reads (16%) | called by mutect2, pindel, varscan2
- TTN | c.18088G>T p.A6030S (on ENST00000591111; = p.A5103S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZER1 | c.228C>G p.D76E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ZFP36L1 | c.791_807del p.P264Rfs*21 | Frame Shift Del (DEL) | VAF 70/206 reads (34%) | called by pindel, varscan2
- ZNF225 | c.2002A>T p.K668* | Nonsense Mutation (SNP) | VAF 24/35 reads (69%) | called by muse, mutect2, varscan2
- ZNF774 | c.5G>C p.W2S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- ZNFX1 | c.5471_5473dup p.G1824_L1825insR | In Frame Ins (INS) | VAF 39/162 reads (24%) | called by mutect2, pindel, varscan2
- ABCC1 | c.735C>T p.N245= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as rs1567335031, COSV60690950; called by muse, mutect2, varscan2
- ADAMTS13 | c.3942G>A p.S1314= | Silent (SNP) | VAF 68/127 reads (54%) | catalogued as rs782408438, COSV52471121; called by muse, mutect2, varscan2
- ADAMTS5 | c.2517C>A p.P839= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as COSV53182574; called by muse, mutect2, varscan2
- ANKRD35 | c.1077C>T p.G359= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV62911164; called by muse, mutect2, varscan2
- ARFRP1 | c.249G>A p.Q83= | Silent (SNP) | VAF 96/356 reads (27%) | catalogued as COSV53928575; called by muse, mutect2, varscan2
- ASTL | c.504G>T p.L168= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as COSV60904924; called by muse, mutect2, varscan2
- ATM | c.8178T>A p.A2726= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV53762070; called by muse, mutect2, varscan2
- ATP7A | c.2607A>G p.V869= | Silent (SNP) | VAF 68/69 reads (99%) | catalogued as rs61053012, COSV58451066; ClinVar: benign; called by muse, mutect2, varscan2
- BARHL2 | c.879G>T p.V293= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV64981750; called by muse, mutect2, varscan2
- BCL9 | c.1542C>T p.P514= | Silent (SNP) | VAF 98/280 reads (35%) | catalogued as rs199517580, COSV52348175; called by mutect2, varscan2
- BCR | c.2175G>C p.L725= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- BEST3 | c.789C>T p.G263= | Silent (SNP) | VAF 62/114 reads (54%) | catalogued as rs1039937279, COSV58303766; called by muse, mutect2, varscan2
- BIN1 | c.688C>T p.L230= (on ENST00000316724 / NM_001320642.1; = p.L199= on NM_004305.4) | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as rs757166690, COSV52120635, COSV99388228; called by muse, mutect2, varscan2
- CCDC105 | c.120G>A p.G40= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1461421747; called by muse, mutect2, varscan2
- CCDC50 | c.69C>T p.V23= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV66669095; called by muse, mutect2, varscan2
- CCT5 | c.150A>C p.T50= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV54724926; called by muse, mutect2, varscan2
- CEACAM4 | c.219A>T p.A73= | Silent (SNP) | VAF 90/148 reads (61%) | catalogued as COSV55732573; called by muse, mutect2, varscan2
- CEP170B | c.3531G>C p.R1177= (on ENST00000453495; = p.R1106= on NM_015005.3) | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- CHRNA2 | c.207C>T p.G69= | Silent (SNP) | VAF 82/91 reads (90%) | catalogued as COSV53558913; called by muse, mutect2, varscan2
- CLEC18B | c.387A>T p.A129= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV60578338; called by muse, mutect2, varscan2
- COLGALT2 | c.876G>T p.L292= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV62300121; called by muse, mutect2, varscan2
- CSMD1 | c.7386T>A p.P2462= (on ENST00000520002; = p.P2461= on NM_033225.6) | Silent (SNP) | VAF 59/62 reads (95%) | catalogued as COSV59356974; called by muse, mutect2, varscan2
- CSPG4 | c.2076C>T p.A692= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as rs758931218, COSV57899233; called by muse, mutect2, varscan2
- CTBP2 | c.666C>T p.G222= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs78653489, COSV58332276; called by muse, mutect2, varscan2
- DOCK2 | c.372G>C p.L124= | Silent (SNP) | VAF 54/78 reads (69%) | catalogued as COSV56975934; called by muse, mutect2, varscan2
- EFNA1 | c.312G>A p.L104= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV57597598; called by muse, mutect2, varscan2
- EML5 | c.3030G>A p.L1010= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as COSV61349704; called by muse, mutect2, varscan2
- F10 | c.1113C>A p.G371= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV65022549; called by muse, mutect2, varscan2
- FAM161A | c.81C>T p.V27= | Silent (SNP) | VAF 19/25 reads (76%) | catalogued as rs1348815152, COSV56767576; called by muse, mutect2, varscan2
- FCRL4 | c.486T>C p.N162= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- FLVCR2 | c.1251C>A p.G417= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV53163755; called by muse, mutect2, varscan2
- FN1 | c.5628C>T p.G1876= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV60559443; called by muse, mutect2, varscan2
- FSTL5 | c.1125G>A p.L375= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV60189133; called by muse, mutect2, varscan2
- GPR139 | c.57C>A p.P19= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV58504119; called by muse, mutect2, varscan2
- GRID2 | c.1386T>A p.G462= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV56239012; called by muse, mutect2, varscan2
- GTF3C1 | c.276G>C p.V92= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV55187906; called by muse, mutect2, varscan2
- GTF3C4 | c.555G>C p.L185= | Silent (SNP) | VAF 59/113 reads (52%) | catalogued as COSV64645819; called by muse, mutect2, varscan2
- H3C13 | c.61C>T p.L21= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- HCK | c.768G>A p.E256= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV52945608; called by muse, mutect2, varscan2
- HPS1 | c.1116G>A p.L372= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV57269374; called by muse, mutect2, varscan2
- IFNA4 | c.34C>T p.L12= | Silent (SNP) | VAF 56/71 reads (79%) | catalogued as rs769006725; called by muse, mutect2, varscan2
- INTS11 | c.1209C>T p.G403= | Silent (SNP) | VAF 66/72 reads (92%) | catalogued as COSV60089675; called by muse, mutect2, varscan2
- IZUMO2 | c.558G>A p.Q186= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV53230906; called by muse, mutect2, varscan2
- KANK4 | c.1317C>T p.S439= | Silent (SNP) | VAF 122/234 reads (52%) | catalogued as COSV62988242; called by muse, mutect2, varscan2
- KCNH8 | c.756C>A p.S252= | Silent (SNP) | VAF 253/376 reads (67%) | catalogued as COSV60471534; called by muse, mutect2, varscan2
- KIAA0930 | c.384G>A p.G128= (on ENST00000336156 / NM_001009880.2; = p.G133= on NM_015264.2) | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs561694948, COSV52664506; called by muse, mutect2, varscan2
- KIF26A | c.3609C>G p.A1203= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- KIF4B | c.492G>T p.R164= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV70527275, COSV70530597; called by muse, mutect2, varscan2
- LAMA2 | c.3804T>C p.S1268= | Silent (SNP) | VAF 69/135 reads (51%) | catalogued as COSV70352517; called by muse, mutect2, varscan2
- LONP1 | c.2634C>A p.A878= | Silent (SNP) | VAF 63/74 reads (85%) | catalogued as rs748466230, COSV56799248; called by muse, mutect2, varscan2
- LRTM2 | c.198G>A p.V66= | Silent (SNP) | VAF 109/200 reads (55%) | catalogued as COSV54566010; called by muse, mutect2, varscan2
- MDFI | c.642G>T p.L214= | Silent (SNP) | VAF 108/230 reads (47%) | catalogued as COSV57822548; called by muse, mutect2, varscan2
- MTNR1B | c.849C>G p.P283= | Silent (SNP) | VAF 122/306 reads (40%) | catalogued as COSV57067849, COSV99924895; called by muse, mutect2, varscan2
- MUC16 | c.40389A>G p.R13463= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV66695002; called by muse, mutect2, varscan2
- MYO1F | c.1380C>T p.V460= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as COSV57798308; called by muse, mutect2, varscan2
- NCF4 | c.450C>G p.L150= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV50625379; called by muse, mutect2, varscan2
- NDUFAF5 | c.195G>A p.P65= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV52524950; called by muse, mutect2
- NEDD4 | c.2100C>A p.A700= (on ENST00000508342 / NM_001284338.1; = p.A281= on NM_006154.4) | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV59064698; called by muse, mutect2, varscan2
- NFATC2 | c.2613C>T p.S871= | Silent (SNP) | VAF 53/181 reads (29%) | catalogued as COSV65359125; called by muse, mutect2, varscan2
- NOL6 | c.1047G>T p.G349= | Silent (SNP) | VAF 109/266 reads (41%) | catalogued as COSV53044507; called by muse, mutect2, varscan2
- NOTCH1 | c.345C>T p.G115= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV53075400; called by muse, mutect2, varscan2
- NRBF2 | c.381G>T p.L127= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- NTAN1 | c.621A>T p.R207= | Silent (SNP) | VAF 155/333 reads (47%) | catalogued as COSV55075223; called by muse, mutect2, varscan2
- OPRK1 | c.921T>C p.A307= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV55568487; called by muse, mutect2, varscan2
- OR4D1 | c.60C>G p.T20= | Silent (SNP) | VAF 118/221 reads (53%) | catalogued as COSV52125692; called by muse, mutect2, varscan2
- OXER1 | c.1134C>T p.G378= | Silent (SNP) | VAF 55/58 reads (95%) | catalogued as COSV54312326; called by muse, mutect2, varscan2
- P2RY14 | c.318C>T p.Y106= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as rs753882142, COSV56389598; called by muse, mutect2, varscan2
- PAPSS2 | c.243C>G p.V81= | Silent (SNP) | VAF 78/130 reads (60%) | catalogued as COSV63264474; called by muse, mutect2, varscan2
- PCDHA6 | c.2049G>A p.S683= | Silent (SNP) | VAF 94/129 reads (73%) | catalogued as rs1305649998, COSV65346227; called by muse, mutect2, varscan2
- PIP4K2C | c.441G>C p.R147= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as COSV61606680; called by muse, mutect2, varscan2
- PITPNM2 | c.1734G>T p.V578= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV54905291; called by muse, mutect2, varscan2
- PKD1 | c.364C>T p.L122= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- PKNOX2 | c.57C>A p.V19= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV53551125; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1002T>C p.N334= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as COSV65049156; called by muse, mutect2
- PPP1R10 | c.1314G>T p.L438= | Silent (SNP) | VAF 69/146 reads (47%) | catalogued as rs1185400915, COSV64740018; called by muse, mutect2, varscan2
- PTK6 | c.852G>A p.L284= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as rs188563979; called by muse, mutect2, varscan2
- RDM1 | c.534C>T p.G178= | Silent (SNP) | VAF 127/138 reads (92%) | called by muse, mutect2, varscan2
- RGS9 | c.1674G>A p.E558= | Silent (SNP) | VAF 110/289 reads (38%) | catalogued as COSV52227661; called by muse, mutect2, varscan2
- SEC24C | c.1155T>A p.S385= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV59543826; called by muse, mutect2, varscan2
- SF3B3 | c.3447G>T p.R1149= | Silent (SNP) | VAF 122/251 reads (49%) | catalogued as COSV56789782; called by muse, mutect2, varscan2
- SH2B2 | c.723G>C p.G241= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- SIPA1 | c.2631G>C p.L877= | Silent (SNP) | VAF 72/146 reads (49%) | catalogued as rs756781327, COSV58015581; called by muse, mutect2, varscan2
- SLC40A1 | c.1305G>T p.G435= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV53724235; called by muse, mutect2, varscan2
- SMO | c.1617G>A p.K539= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as COSV50836289; called by muse, mutect2, varscan2
- SNTG2 | c.540C>T p.S180= | Silent (SNP) | VAF 130/150 reads (87%) | catalogued as rs368006432; called by muse, mutect2, varscan2
- SNX14 | c.2139A>G p.L713= (on ENST00000314673 / NM_001350535.1; = p.L660= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as COSV59014636; called by muse, mutect2, varscan2
- SOX8 | c.765G>T p.G255= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV53510119; called by muse, mutect2, varscan2
- SPATA31D1 | c.2454G>T p.G818= | Silent (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- SPTA1 | c.6135C>T p.F2045= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs369162735; called by muse, mutect2, varscan2
- TEAD2 | c.114C>A p.G38= | Silent (SNP) | VAF 80/123 reads (65%) | catalogued as COSV55563078; called by muse, mutect2, varscan2
- TEP1 | c.252A>T p.T84= | Silent (SNP) | VAF 76/150 reads (51%) | catalogued as COSV52995745, COSV52996889; called by muse, mutect2, varscan2
- TEPSIN | c.318G>C p.G106= | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as COSV56144028; called by muse, mutect2, varscan2
- TESPA1 | c.507C>A p.G169= (on ENST00000316577 / NM_001098815.3; = p.G31= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 75/145 reads (52%) | catalogued as COSV57260280; called by muse, mutect2, varscan2
- TEX35 | c.75G>A p.K25= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV51106916; called by muse, mutect2, varscan2
- TLR8 | c.2541G>C p.L847= (on ENST00000218032 / NM_138636.5; = p.L865= on NM_016610.4) | Silent (SNP) | VAF 74/84 reads (88%) | catalogued as COSV54319530; called by muse, mutect2, varscan2
- TRIML1 | c.1338C>A p.S446= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV60193400, COSV60195916; called by muse, mutect2, varscan2
- TTN | c.93810G>A p.K31270= (on ENST00000591111; = p.K23846= on NM_003319.4) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV60226768; called by muse, mutect2, varscan2
- TUBB2A | c.651G>C p.L217= | Silent (SNP) | VAF 58/172 reads (34%) | catalogued as COSV61319365; called by muse, mutect2, varscan2
- TUBGCP6 | c.3912A>G p.S1304= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV50565988; called by muse, mutect2, varscan2
- UCK2 | c.303C>T p.I101= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as rs746717566, COSV63316339; called by muse, mutect2, varscan2
- UROD | c.708C>T p.Y236= | Silent (SNP) | VAF 69/72 reads (96%) | catalogued as COSV55801495; called by muse, mutect2, varscan2
- VENTX | c.537C>T p.G179= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1267202291, COSV58085074; called by muse, mutect2, varscan2
- VIM | c.1035T>C p.R345= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV56407007; called by muse, mutect2, varscan2
- VIPR2 | c.1092G>A p.G364= | Silent (SNP) | VAF 73/149 reads (49%) | catalogued as COSV51113139; called by muse, mutect2, varscan2
- WDR1 | c.1104G>T p.V368= (on ENST00000382452; = p.V228= on NM_005112.5) | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV66724439, COSV66725627; called by muse, mutect2, varscan2
- ZMYND8 | c.780A>G p.L260= (on ENST00000311275 / NM_001363741.2; = p.L280= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV53693399; called by muse, mutect2, varscan2
- ZNF143 | c.1008G>T p.R336= | Silent (SNP) | VAF 78/88 reads (89%) | catalogued as COSV55181577; called by muse, mutect2, varscan2
- ZNF653 | c.327G>A p.K109= | Silent (SNP) | VAF 151/716 reads (21%) | catalogued as rs1047296915, COSV53404099; called by muse, mutect2, varscan2
- ZP1 | c.12C>G p.G4= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as rs779180617, COSV53925691; called by muse, mutect2, varscan2
- ZSCAN10 | c.837G>T p.V279= (on ENST00000252463; = p.V334= on NM_032805.3) | Silent (SNP) | VAF 106/261 reads (41%) | catalogued as COSV52969704; called by muse, mutect2, varscan2
- ZXDA | c.817C>T p.L273= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV62388481; called by muse, mutect2, varscan2
- CALM1 | c.*2G>T | 3'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100811142; called by muse, mutect2, varscan2
- CD74 | c.-1G>A | 5'UTR (SNP) | VAF 163/217 reads (75%) | catalogued as COSV99154276; called by muse, mutect2, varscan2
- DCHS2 | n.6368G>T | RNA (SNP) | VAF 61/135 reads (45%) | catalogued as COSV61774766, COSV61776827; called by muse, mutect2, varscan2
- DLK2 | c.*1T>C | 3'UTR (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99767992; called by muse, mutect2, varscan2
- DPF3 | c.871+2991G>C | Intron (SNP) | VAF 50/107 reads (47%) | catalogued as COSV63501735; called by muse, mutect2, varscan2
- EEF1D | c.-7-2768G>T | Intron (SNP) | VAF 25/43 reads (58%) | catalogued as COSV57821717; called by muse, mutect2, varscan2
- EI24P4 | n.975T>A | RNA (SNP) | VAF 125/289 reads (43%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457651 G>C | 5'Flank (SNP) | VAF 23/122 reads (19%) | catalogued as rs775270811; called by muse, mutect2, varscan2
- NOTCH2NLA | c.-260G>C | 5'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100757451; called by muse, mutect2, varscan2
- SSPOP | n.2889G>A | RNA (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- TRDC | c.*45C>T | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- TTI2 | chr8:33513537 C>A | 5'Flank (SNP) | VAF 62/73 reads (85%) | catalogued as COSV100659821; called by muse, mutect2, varscan2
- XIST | n.8154G>A | RNA (SNP) | VAF 29/35 reads (83%) | called by muse, mutect2, varscan2
